Surgical pathology report (de-identified scan), TCGA case TCGA-FZ-5922, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-FZ-5922-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: GALLBLADDER, RESECTION –
NO SIGNIFICANT ABNORMALITY.

PART 2: DISTAL DUODENUM, RESECTION –
A. SUBMUCOSAL HEMATOMA; OTHERWISE NO SIGNIFICANT ABNORMALITY.
B. ONE BENIGN LYMPH NODE.

PARTS 3, 4 AND 5: HEAD OF PANCREAS, RESECTION–
A. INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED (1.8 CM).
B. ALL MARGINS OF RESECTION FREE OF CARCINOMA.
C. PERINEURAL AND ANGIOLYMPHATIC INVASION IS PRESENT.
D. TUMOR EXTENDS FOCALLY INTO PERI-PANCRATIC TISSUE, BUT INVOLVES NEITHER DUODENAL WALL NOR AMPULLA OF VATER.
E. FIVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/5); HOWEVER, CARCINOMATOUS CELLS ARE PRESENT IN LYMPHATIC SPACES ADJACENT TO ONE LYMPH NODE.
F. PATHOLOGIC STAGE: pT3 N0 MX.
G. UNINVOLVED PANCREAS WITH CHRONIC PANCREATITIS AND SCATTERED LOW-GRADE PANCREATIC INTRAEPITHELIAL NEOPLASIA (PanIN).
H. INCIDENTAL ATROPHIC HETEROTOPIC PANCREAS IN DUODENAL WALL; DUODENUM IS OTHERWISE UNREMARKABLE.

SYNOPTIC DATA - PRIMARY PANCREAS(EXOCRINE) TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy
TUMOR SITE: Pancreatic head
TUMOR SIZE: Greatest dimension: 1.8 cm
Additional dimensions: 1.6 x 1.1 cm
OTHER ORGANS RESECTED: Gallbladder

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Ductal adenocarcinoma
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM): pT3
pN0
Number of lymph nodes examined: 5
Number of lymph nodes involved: 0
pMX
MARGINS: Common bile duct margin uninvolved
Pancreatic parenchymal margin uninvolved
Uncinate process/retroperitoneal margin uninvolved
SMV/portal vein notch margin uninvolved
Proximal duodenal/gastric margin uninvolved
Distal duodenal margin uninvolved

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

PERINEURAL INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: Present

Comment: Pancreatic intraepithelial neoplasia (highest grade: PanIN Low Ib)
Chronic pancreatitis

No definite lymph node metastasis is identified, but carcinomatous cells are present in lymphatic spaces adjacent to one lymph node.

Source: NCI Genomic Data Commons file bfcce281-6ad3-4051-bbfa-e47915968a1d (TCGA-FZ-5922.3AAEAE69-9C36-499F-9177-A04860659690.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).